Surgical pathology report (de-identified scan), TCGA case TCGA-FU-A5XV, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FU-A5XV-01A (Primary Tumor).

[page 1 of 3]
Sex: Female
D.O.B.:
MRN #
Ref Physician:

SPECIMEN INFORMATION

Collected: Accession #:
Received: Acct / Reg #:
Reported: 1

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Right pelvic sidewall, biopsy:
Negative for malignancy.
- B. Right external iliac lymph nodes, excision:
One of two lymph nodes positive for metastatic carcinoma.
Endosalpingiosis.
Frozen section discordance due to sampling error.
- C. Left obturator lymph nodes, excision:
One of one lymph node positive for metastatic carcinoma.
Endosalpingiosis.
- D. Right uterine artery, biopsy:
Negative for malignancy.
- E. Radical hysterectomy specimen:
Tumor Characteristics:
1. Histologic type: Squamous cell carcinoma.
2. Histologic grade: 2-3, moderate to poorly differentiated.
3. Tumor site: Endocervix.
4. Tumor size: 4.5 x 3.5 x 2.5 cm.
5. Stromal invasion/depth/horizontal extent: Tumor extends 1.5 cm into a 1.8 cm thick cervical wall.
6. Lymphovascular space invasion: Present and extensive.**Surgical Margin Status:**
1. Vaginal margin negative.
2. Deep margin negative.**Lymph Node Status:**
1. Total number of lymph nodes received: 63.
2. Total number of lymph nodes containing metastatic carcinoma: 2.**Other:**
1. Other significant findings:
- a. Endometrium and myometrium without significant abnormality.
- b. Tumor focally extends into the lower uterine segment.
2. pTNM stage: pT1b2N1 (FIGO IB2).
- F. Right external iliac lymph nodes #2, excision:
9 lymph nodes, negative for metastatic disease.
- G. Right obturator lymph nodes, excision:
16 lymph nodes, negative for metastatic disease.
- H. Right common lymph nodes, excision:
7 lymph nodes, negative for metastatic disease.
- I. Left external iliac lymph nodes, excision:
11 lymph nodes, negative for metastatic disease.
Endosalpingiosis.
- J. Left obturator lymph nodes, excision:
10 lymph nodes, negative for metastatic disease.
Endosalpingiosis.
- K. Left common lymph nodes, excision:
7 lymph nodes, negative for metastatic disease.
Endosalpingiosis.

ICD-O-3
Carcinoma, squamous cell NOS
path 8070/3
Site Endocervix C53.0
+ Cervix C53.9
grd 5/10/13

[page 2 of 3]
DIAGNOSIS

Electronic Signature:

COMMENTS:

Appropriately controlled immunohistochemical stains performed on blocks B1 and C1 show the following results:

- WT1 - Positive in foci of endosalpingiosis.
- Monoclonal CEA - Focally positive in carcinoma.
- p16 - Strongly positive in carcinoma and weakly positive in endosalpingiosis.

These findings are consistent with metastatic squamous carcinoma in lymph nodes with associated foci of endosalpingiosis.

Additional stains performed on block E9 show tumor cells positive for p63 and negative for CK7, consistent with squamous carcinoma.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Cervical cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right pelvic sidewall
- B. Right external iliac FS
- C. Left obturator
- D. Right uterine artery
- E. Radical hysterectomy specimen
- F. Right external iliac #2
- G. Right obturator
- H. Right common
- I. Left external iliac
- J. Left obturator
- K. Left common

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in eleven containers labeled with the patient's name

- A. Container A is additionally labeled right pelvic sidewall and contains a 2.5 x 1.4 x 0.7 cm yellow gray fibromembranous soft tissue with adherent yellow tan adipose tissue. Nodules or lesions are not identified. The bisected specimen is entirely submitted in cassette A1 labeled
- B. Container B is additionally labeled right external iliac and contains a 4.5 x 2.5 x 1.0 cm aggregate of yellow tan lobulated fibrofatty soft tissue. Two pink tan rubbery nodules are identified possibly consistent with lymph nodes. They are 2.4 and 2.5 cm in greatest dimension. These nodules are entirely submitted for frozen section with the residual entirely resubmitted for permanent section in cassette B1 labeled
- C. Container C is additionally labeled left obturator and contains a 2.4 x 2.0 x 1.0 cm yellow tan lobulated fibrofatty soft tissue. The specimen is sectioned to reveal a 1.5 cm wall dominated nodule consistent with lymph node. The extraneous fat is trimmed and the bisected nodule is entirely submitted in cassette C1 labeled
- D. Container D is additionally labeled right uterine artery and contains a 3.0 x 1.5 x 1.5 cm yellow tan lobulated fibrofatty soft tissue. Sectioning reveals a central coarse thick walled vessel consistent with artery. Multiple embedded staples and clips are also present. The clips and staples are removed and the remainder of the specimen is submitted in cassette D1 labeled
- E. Container E is additionally labeled radical hysterectomy specimen and contains a 191 gram radical hysterectomy specimen comprised of uterine corpus (5.5 x 5.5 x 4.2 cm), uterine cervix (4.0 cm in length by 4.5 x 3.2 cm), vaginal cuff (ranging from 0.7 up to 2.0 cm in length), right paracervical soft tissues (4.0 x 3.5 x 1.2 cm), and left paracervical soft tissues (4.4 x 4.0 x 2.3 cm). Adnexae are not present. The soft tissue margins are inked. On sectioning and palpation, a possible 0.3 cm paracervical lymph node is identified on the left side. The vaginal mucosa is pink tan and wrinkled with no discrete lesions. The ectocervical mucosa is pink tan and glistening and features a central 1.5 cm patent os. The endocervical canal is remarkable for a 4.5 x 3.5 x 2.5 cm pink tan friable mass that is grossly confined to the endocervix and approaches to within 1.5 cm of the vaginal cuff margin. This mass extends 1.5 cm into a 1.6 cm thick cervix. The triangular endometrium is pink tan and glistening with an average thickness of 0.2 cm. The surrounding myometrium is pink tan and fibrous with an average thickness of 1.8 cm. No myometrial nodules or lesions are identified. Representative sections are submitted in cassettes E1-E15 labeled and designated as follows: E1-right paracervical soft tissues, perpendicular; E2-left paracervical soft

[page 3 of 3]
SPECIMEN INFORMATION

tissues, perpendicular; E3—one whole possible left paracervical lymph node; E4—anterior vaginal cuff margin, en-face; E5—posterior vaginal cuff margin, en-face; E6—anterior lower uterine segment; E7—posterior lower uterine segment; E8 to E13—cervical lesion to inked deep margin at greatest extent of invasion; E14—full thickness anterior endomyometrium; E15—full thickness posterior endomyometrium. Additionally, a yellow, green and blue cassette are submitted for genomic research labeled

F. Container F is additionally labeled right external iliac #2 and contains a 7.5 x 4.0 x 2.5 cm aggregate of yellow tan lobulated fibrofatty soft tissue. On palpation, nine firm fatty possible lymph nodes are identified ranging from 0.4 up to 2.5 cm in greatest dimension. They are entirely submitted in cassettes F1-F4 labeled designated as follows: F1—four whole possible lymph nodes; F2—three whole possible lymph node; F3 and F4—one whole possible bisected lymph node in each cassette.

G. Container G is additionally labeled right obturator and contains a 4.5 x 3.0 x 1.5 cm aggregate of yellow tan lobulated fibrofatty soft tissue. On palpation, multiple firm fatty possible lymph nodes are identified ranging from 0.2 up to 1.7 cm. They are entirely submitted in cassettes G1-G4 labeled designated as follows: G1—three whole possible lymph nodes; G2 and G4—four whole possible lymph nodes in each cassette; G3—one whole possible bisected lymph node.

H. Container H is additionally labeled right common and contains a 3.0 x 2.0 x 1.2 cm aggregate of yellow tan lobulated fibrofatty soft tissue. On palpation, multiple firm fatty possible lymph nodes are identified ranging from 0.4 up to 2.0 cm in greatest dimension. They are entirely submitted in cassettes H1 and H2 labeled

I. Container I is additionally labeled left external iliac and contains a 4.8 x 4.4 x 2.5 cm aggregate of yellow tan lobulated fibrofatty soft tissue. On sectioning and palpation, multiple firm fatty possible lymph nodes are identified ranging from 0.4 up to 3.1 cm in greatest dimension. They are entirely submitted in cassettes I1-I5 labeled designated as follows: I1—one whole possible lymph node; I2—four whole possible lymph nodes; I3—three whole possible lymph nodes; I4—two whole possible bisected lymph nodes (one inked); I5—one whole possible bisected lymph node.

J. Container J is additionally labeled left obturator and contains a 5.0 x 4.0 x 2.0 cm aggregate of yellow tan lobulated fibrofatty soft tissue. On sectioning and palpation, multiple firm fatty possible lymph nodes are identified ranging from 0.3 up to 2.1 cm in greatest dimension. They are entirely submitted in cassettes J1-J4 labeled designated as follows: J1—five whole possible lymph nodes; J2—four whole possible lymph nodes; J3 and J4—one whole possible bisected lymph node.

K. Container K is additionally labeled left common and contains a 4.4 x 3.5 x 1.8 cm aggregate of yellow tan lobulated fibroadipose tissue. On palpation, seven firm fatty possible lymph nodes are identified ranging from 0.5 up to 2.4 cm in greatest dimension. They are entirely submitted in cassettes K1-K3 labeled designated as follows: K1—four whole possible lymph nodes; K2—two whole possible bisected lymph nodes (one inked); K3—one whole possible bisected lymph node.

INTERPRETATIVE CONSULTATION:
FROZEN SECTION DIAGNOSIS B: "Negative"

Source: NCI Genomic Data Commons file d5c3bf70-769d-4aa3-b5fe-0f80f444122f (TCGA-FU-A5XV.650F9C07-D8FB-46BD-8565-D03E83F049D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).